Surgical pathology report (de-identified scan), TCGA case TCGA-XE-AAO5, project TCGA-TGCT (Testicular Germ Cell Tumors), specimen TCGA-XE-AAO5-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY TISSUE REPORT

Name:

- Specimen Source: L TESTICLE AND CORD
- Gross Exam Date:
- Physician:

ICD-O-3
Mixed germ cell tumor 9085/3
Site @ Testis NOS 62.9
Pager No.: 953/2114

PRELIMINARY DIAGNOSIS (based on GROSS and MICROSCOPIC examination):

- 1) MIXED GERM CELL TUMOR COMPOSED OF EMBRYONAL CARCINOMA (70%), YOLK SAC TUMOR (15%), MATURE AND IMMATURE TERATOMA (15%) AND EXTENSIVE NECROSIS, orchiectomy. (see note)
- 2) INTRATUBULAR GERM CELL NEOPLASIA.
- 3) TUMOR APPEARS CONFINED TO THE TESTES.
- 4) LYMPHOVASCULAR INVASION IS NOT DEFINITELY IDENTIFIED.
- 5) SURGICAL MARGINS FREE OF TUMOR.
- 6) TUMOR STAGE T1NXMX.

Note: The tumor is CD30, CAM 5.2 and AFP positive and HCG negative and c-Kit negative. PLAP is positive in the intratubular germ cell neoplasia. Although embryonal carcinoma is noted in a vascular space, they are interpreted as likely carry-over artifact because of their discohesiveness. Clinico-pathological correlation recommended.

GROSS DESCRIPTION:

The specimen is received in one part in formalin labeled with the patient's name, and "left testicle and cord". It consists of a 110 gram orchiectomy specimen including 5.5x4x4 cm testes, 1.5x1x0.7 cm epididymis and 12 cm in length and 1.5 cm in diameter spermatic cord. The outer surface is inked in blue. The testes is already opened along the hilum showing tan to brown necrotic mass with hemorrhagic area measuring 3.7x2.5x2 cm. Tumor is 0.3 cm at the closest approach to tunica albuginea.

There is no gross involvement of the tunica albuginea or impingement on the epididymis. The rim of testicular parenchyma at the edge of the tumor is compressed and grossly unremarkable. The spermatic cord consists of vas deferens, arteries and veins and is unremarkable. R11.

SUMMARY OF CASSETTES:

IN PT. ☐ COST CODE	CLINIC/WARD/NURSING STATION	PATIENT IDENTIFICATION
---	-----------------------------	------------------------

SURGICAL PATHOLOGY TISSUE REPORT

[page 2 of 3]
Name:

Sex:

Operative Procedure: ORCHIECTOMY

- Specimen Source: L TESTICLE AND CORD
- Gross Exam Date:
- Physician:

Pager No.:

Cassette #1 - epididymis.
Cassettes #2 - #4 - tumor and tunica albuginea.
Cassette #5 - tumor alone.
Cassette #6 - spermatic cord resection margin.
Cassette #7 - spermatic cord mid-portion.
Cassette #8 - spermatic cord pre-testicular portion.

IN PT. ☐ COST CODE	CLINIC/WARD/NURSING STATION	PATIENT IDENTIFICATION
---	-----------------------------	------------------------

SURGICAL PATHOLOGY TISSUE REPORT

*Pw TSS dx discrepancy form,
TCGA tumor is Embryonal 70%
Seminoma 30%*

PAGE 2

[page 3 of 3]
TCGA Pathologic Diagnosis Discrepancy Form

V4.00

Instructions: The TCGA Pathologic Diagnosis Discrepancy Form should be completed when the pathologic diagnosis documented on the initial pathology report for a case submitted for TCGA is inconsistent with the diagnosis provided on the Case Quality Control Form completed for the submitted case.

Tissue Source Site (TSS) _____ TSS Identifier: _____ TSS Unique Patient Identifier: _____

Completed By (Interviewer Name on OpenClinica): _____ Completed Date: _____

Diagnosis Information

#	Data Element	Entry Alternatives	Working Instructions
1	Pathologic Diagnosis Provided on Initial Pathology Report	Embryonal Carcinoma 70%, Yolk Sac Tumor 15%, Mature and Immature Teratoma 15%,	Provide the diagnosis/ histologic subtype(s) documented on the initial pathology report for this case. If the histology for this case is mixed, provide all listed subtypes.
2	Histologic features of the sample provided for TCGA, as reflected on the CQCF.	Embryonal Carcinoma 70%, Seminoma 30%	Provide the histologic features selected on the TCGA Case Quality Control Form completed for this case.

Discrepancy between Pathology Report and Case Quality Control Form

3	Provide the reason for the discrepancy between the pathology report and the TCGA Case Quality Control Form.	histologic heterogeneity characteristic of mixed germ cell tumors	Provide a reason describing why the diagnosis on the initial pathology report for this case is not consistent with the diagnosis selected on the TCGA Case Quality Control Form.
4	Name of TSS Reviewing Pathologist or Biorepository Director		Provide the name of the pathologist who reviewed this case for TCGA.

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled.

TSS Reviewing Pathologist or Biorepository Director

Date

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled. The Attending Pathologist or the Department Chairman has been informed or is aware of the above discrepancy in diagnoses.

Principal Investigator Signature

Date

Source: NCI Genomic Data Commons file d0705610-3214-4e59-a6aa-3f0dd2185ce2 (TCGA-XE-AAO5-01A.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).